Surgical pathology report (de-identified scan), TCGA case TCGA-05-4433, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4433-01A (Primary Tumor).

Main diagnosis/diagnoses:

Peripheral bronchopulmonary, histologically mucinous adenocarcinoma with very predominant bronchioloalveolar differentiation and spread and a small component showing destructive, infiltrative growth and localization in S10.

TNM classification on the basis of this material pT2 pN0 pMX R0 stage IB.

C34.3 M 8255/3.

Comment/supplementary remark:

There is no evidence of the carcinoma having infiltrated the visceral pleura. The resection margin of the bronchus and vessels and all the removed lymph nodes are also tumor-free.

Source: NCI Genomic Data Commons file 1d3b16d5-61bf-4032-8ee4-4e8e49bca50d (TCGA-05-4433.EEAE318D-A517-48B6-9A21-5C72DC4BD510.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).